Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5515, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5515-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 4.8, left-sided varicocele, two [REDACTED] his biopsy reveals unilateral poorly differentiated prostatic adenocarcinoma on the right side. The patient also has a history of biopsy on [REDACTED] his

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Prostate cancer.

PROCEDURE: Radical retropubic prostatectomy.

SPECIFIC CLINICAL QUESTION: Not given.

OUTSIDE TISSUE DIAGNOSIS: Not given.

PRIOR MALIGNANCY: Not given.

CHEMOTHERAPY: Not given.

ORGAN TRANSPLANT: Not given.

IMMUNOSUPPRESSION: Not given.

OTHER DISEASES: Not given.

FINAL DIAGNOSIS:

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN THREE LYMPH NODES EXAMINED (0/3).

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN SEVENTEEN LYMPH NODES EXAMINED (0/17).

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7 WITH MINOR GLEASON GRADE 5 COMPONENT COMPRISING 2% OF THE ENTIRE TUMOR VOLUME AND SHOWING FEATURES OF DUCTAL CARCINOMA (See synoptic).
- B. THE CARCINOMA INVOLVES THE RIGHT LOBE ONLY AND HAS A GREATEST NODULAR DIAMETER OF 1.6 cm.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 5% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS FOCAL EXTRACAPSULAR EXTENSION IN THE POSTERIOR RIGHT MID (SLIDE 3U) AND POSTERIOR RIGHT BASE (SLIDE 3V) CAPSULAR MARGIN REGIONS.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. THE CARCINOMA IS PRESENT WITHIN 2 CELL LAYERS FROM THE INKED POSTERIOR RIGHT MID CAPSULAR MARGIN, HOWEVER ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. MULTIFOCAL PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. MULTIFOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT3a N0 Mx.
- K. TNM HISTOLOGIC GRADE = G3-4.
- L. BENIGN PROSTATIC HYPERTROPHY AND CHRONIC INFLAMMATION ARE NOTED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 4.8
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	40%
WEIGHT OF PROSTATE:	36.38gm
TUMOR SIZE:	Maximum dimension: 1.6 cm
LOBE LATERALITY:	Right Lobe
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	No
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Focal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	20
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMx
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Comment: There is a minor Gleason grade 5 component comprising 2% of the total tumor volume.

TCGA - EJ - 5515

Source: NCI Genomic Data Commons file be620967-74a5-45ab-864c-687bbe88f3dd (TCGA-EJ-5515.1029BA11-EFB4-42B7-871C-C97192A40E12.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).